Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7434, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7434-01A (Primary Tumor).

[page 1 of 3]
SUPPLEMENTAL REPORT

DIAGNOSIS:

- (D) LEFT SEGMENTAL MANDIBULECTOMY, PARTIAL MAXILLECTOMY, RIGHT SUPRAHYOID NECK DISSECTION, PARTIAL GLOSSECTOMY, TUMOR FLOOR OF MOUTH:
INVASIVE SQUAMOUS CELL CARCINOMA INVOLVES MANDIBULAR BONE.
(SEE COMMENT)
Bone margins of resection free of tumor.

COMMENT:

This supplemental report is being issued to provide results on tissue which underwent decalcification. The diagnosis otherwise remains unchanged.

ADDITIONAL GROSS:

- (D) LEFT SEGMENTAL MANDIBULECTOMY, PARTIAL MAXILLECTOMY, RIGHT SUPRAHYOID NECK DISSECTION, PARTIAL GLOSSECTOMY, TUMOR FLOOR OF MOUTH -
SECTION CODE: D32 and D33, mandibular bone margins, en face; D34 and D35, mandibular bone and tumor.

DIAGNOSIS

- (A) LEFT MENTAL NERVE:
Segment of nerve, no tumor present.
- (B) RIGHT MENTAL NERVE :
Segment of nerve, no tumor present.
- (C) TEETH :
Five teeth. (gross only)
- (D) LEFT SEGMENTAL MANDIBULECTOMY, PARTIAL MAXILLECTOMY, RIGHT SUPRAHYOID NECK DISSECTION, PARTIAL GLOSSECTOMY, TUMOR FLOOR OF MOUTH:
INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED,
INVOLVING FLOOR OF MOUTH. (SEE COMMENT)
PERINEURAL INVASION PRESENT.
No vascular/lymphatic invasion identified.

[page 2 of 3]
[REDACTED]

Final margins of resection free of tumor. (see comment)

METASTATIC SQUAMOUS CELL CARCINOMA IN 1 OF 1 RIGHT LEVEL I LYMPH NODE
(0.8 CM DIAMETER FOCUS WITH EXTRACAPSULAR EXTENSION).

- (E) CONTENTS LEFT MAXILLARY INTERIM:
Respiratory mucosa and fragments of bone, no tumor present.
- (F) ADDITIONAL DEEP MARGIN LEFT SUBMANDIBULAR:
Fibroadiopose tissue and skeletal muscle, no tumor present.
- (G) NEW MAXILLARY MARGIN:
Squamous mucosa and salivary gland tissue, no tumor present.
- (H) NEW BASE OF TONGUE:
Squamous mucosa and skeletal muscle, no tumor present.
- [REDACTED]

COMMENT

In specimen D, two foci of invasive tumor are present involving the floor of the mouth. These foci of invasive tumor are 5.0 cm and 4.0 cm in greatest dimension. Tumor focally extends to the floor of mouth and left posterior pharyngeal wall mucosal/soft tissue margins; however, additional tissue from these areas has been submitted as specimens G and H which do not contain tumor. Thus, the final margins of resection are free of tumor.

The portion of bone is pending decalcification. The results will follow in a supplemental report.

[REDACTED]

GROSS DESCRIPTION

(A) LEFT MENTAL NERVE (STITCH = TRUE MARGIN) - The specimen consists of a strand of pink-tan soft tissue (0.8 cm in length and 0.2 cm in greatest diameter) with a stitch marking the true surgical margin. Black ink is applied to the true surgical margin and the entire specimen is submitted en face for frozen section. [REDACTED]

*FS/DX: SEGMENT OF NERVE, NO TUMOR PRESENT. [REDACTED]

(B) RIGHT MENTAL NERVE (RULE OUT PERINEURAL INVASION, STITCH OLD MARGIN) - Single segment of nerve (0.7 cm in length and 0.1 cm in diameter). The true margin is marked with black ink and the specimen is submitted entirely in B for frozen section diagnosis. [REDACTED]

*FS/DX: SEGMENT OF NERVE, NO TUMOR PRESENT. [REDACTED]

(C) TEETH - Five teeth ranging in size from 2.1 to 2.7 cm in greatest dimension. Four of the teeth are notable for dental caries and evidence of repair. The specimen is returned to [REDACTED].

(D) LEFT SEGMENTAL MANDIBULECTOMY - A portion of mandible (from left ramus to right mid mandible), 18.0 x 7.0 x 4.0 cm, attached level I right neck dissection (5.0 x 3.0 x 2.0 cm), and attached floor of mouth and left pharyngeal wall (7.0 x 4.0 x 2.0 cm).

In the center of the floor of mouth is a white glistening tumor (4.0 x 3.0 x 2.5 cm). It grossly extends to within 0.5 cm of the deep margin and closely

[page 3 of 3]
approaches the mucosal margin. There is a separate satellite mass in the left pharyngeal tissue (5.0 x 3.0 x 2.0 cm) that grossly extends to the left lateral pharyngeal mucosal margins. In the left right level I neck dissection, two possible lymph nodes are palpated (2.0 x 2.0 x 1.0 cm and 1.0 x 1.0 x 0.5 cm), both of which appear to be involved by metastatic tumor. The satellite nodule in the left pharyngeal tissue extends into the surrounding muscle and tendon.

INK CODE: Blue - deep margin of tumor.

SECTION CODE: (D1-D17 for frozen; D1-D16 en face). D1, anterior alveolar ridge right side; D2, mid alveolar ridge; D3, left side alveolar ridge; D4-D7, left pharyngeal margin; D8-D9, posterior left pharyngeal margin; D10-D13, posterior floor of mouth; D14-D16, right floor of mouth; D17, perpendicular deep margin; D18-D22, main tumor mass; D23-D26, satellite tumor mass; D27, D28, larger lymph node from right level 1; D29, D30, smaller lymph node from right side neck level 1; D31, possible salivary gland. The specimen is sent to bone lab and sectioning of mandible. [REDACTED]

*FS/DX: DEEP MARGIN OF RESECTION FREE OF TUMOR. INVASIVE SQUAMOUS CELL CARCINOMA PRESENT AT FLOOR OF MOUTH MARGIN. SUPERFICIALLY INVASIVE SQUAMOUS CELL CARCINOMA AT LEFT POSTERIOR PHARYNGEAL WALL MARGIN. [REDACTED]

(E) CONTENTS, LEFT MAXILLARY INTERIM - One piece of tan, mucoid mucosal tissue (1 x 0.5 x 0.5 cm) submitted entirely in cassette E. [REDACTED]

(F) ADDITIONAL DEEP MARGIN, STITCH TRUE DEEP MARGIN - One piece of fibromuscular connective tissue (4 x 3 x 0.3 cm) with a stitch at one edge of the specimen. No masses are palpated within the soft tissue.

INK CODE: Blue=true margin.

SECTION CODE: F1-F3, entire margin en face. [REDACTED]

(G) NEW MAXILLARY MARGIN (INKED TRUE MARGIN, STITCH SUPERIOR) - The specimen consists of a piece of mucosal tissue (4.0 x 1.0 x 0.5 cm). There is a stitch at one end.

INK CODE: Blue - true margin; yellow - superior edge of each piece.

SECTION CODE: G1, superior half perpendicular section for frozen; G2, inferior half perpendicular section for frozen. [REDACTED]

*FS/DX: SQUAMOUS MUCOSA AND CONNECTIVE TISSUE, NO TUMOR PRESENT. [REDACTED]

(H) NEW BASE OF TONGUE - Specimen consists of one piece of muscle and fibrous tissue, (6.0 x 1.5 x 0.5 cm). There is a stitch marking the anterior margin and the blue ink as the true margin. No masses are palpated in the specimen.

INK CODE: Blue - true margin; yellow - anterior portion of each piece.

SECTION CODE: H1-H5, entire margin perpendicular section for frozen. [REDACTED]

*FS/DX: SQUAMOUS MUCOSA AND CONNECTIVE TISSUE, MARGIN OF RESECTION FREE OF TUMOR. [REDACTED]

SNOMED CODES

M-80703 T-51200

Source: NCI Genomic Data Commons file 055f1466-7abf-418e-84cb-6eb7c72a3611 (TCGA-CV-7434.D14FECF1-7F8E-4EC2-B4B4-83C411A2E05B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).